Gene-level copy-number profile of tumor specimen ALCH-B4VE-TTP1-A from ALCHEMIST case ALCH-B4VE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.5 years (26,483 days).
Specimen ALCH-B4VE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 624d5d24-0305-4e32-8cc1-07be9ad21589.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4VE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/7a208754-9f25-4464-a6c3-98b0b539ce43

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 3,550; copy number 2: 54,365; copy number 3: 459; copy number 4: 11; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,416,351–13,421,328, 1 gene: PRAMEF20.
- chr7:6,615,610–6,658,279, 2 genes: ZNF853, ZNF316.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr22:18,533,646–18,625,289, 6 genes: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:62,796,473–62,805,587, 2 genes, copy number 6 (within-gene range 1–6): MRGBP, OGFR-AS1.

Autosomal genes at a single copy (total copy number 1): 3,550. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
